Gene-level copy-number profile of specimen HCM-BROD-0121-C41-85B from HCMI case HCM-BROD-0121-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 14.2 years (5,196 days).
Specimen HCM-BROD-0121-C41-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00ea2f6f-abb0-4ca9-980c-696724eb8333.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0121-C41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,874 have no estimate.
https://portal.gdc.cancer.gov/files/1bdd82ac-e072-4a52-b858-835efa9c8ac3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 158; copy number 2: 40,010; copy number 3: 4,152; copy number 4: 12,103; copy number 5: 2,104; copy number 6: 157; copy number 7: 54; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,425,384–151,657,966, 5 genes (within-gene range 0–2): IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,320 genes in 67 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:54,330,687–145,066,685, 1,374 genes, copy number 5–7 (broad region; genes not listed).
- chr9:60,914,407–61,666,386, 17 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr12:12,310–6,866,632, 189 genes, copy number 5–8 (broad region; genes not listed).
- chr12:9,951,316–10,030,606, 4 genes, copy number 5 (within-gene range 4–5): CLEC12A, CLEC1B, CLEC12B, AC024224.2.
- chr12:10,226,058–10,454,685, 11 genes, copy number 5: KLRD1, LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1.
- chr12:10,588,063–10,613,609, 2 genes, copy number 5: KLRA1P, MAGOHB.
- chr12:10,845,849–11,590,369, 36 genes, copy number 5 (within-gene range 4–5): PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252.
- chr12:12,049,844–23,188,807, 184 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:25,004,342–25,195,162, 5 genes, copy number 5: IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94.
- chr12:25,385,670–25,834,182, 12 genes, copy number 5: AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2.
- chr12:26,139,249–27,161,393, 22 genes, copy number 5: AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2.
- chr12:27,592,461–27,756,295, 9 genes, copy number 5: AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA.
- chr12:28,821,975–29,381,189, 10 genes, copy number 5: AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.
- chr12:29,658,376–30,296,707, 4 genes, copy number 5: RPL21P99, AC023511.2, AC023511.1, LINC02386.
- chr12:30,454,919–31,254,445, 18 genes, copy number 5: AC026371.1, IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1.
- chr12:31,465,062–31,616,439, 8 genes, copy number 5: AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3.
- chr12:31,729,117–31,959,316, 11 genes, copy number 5 (within-gene range 4–5): AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32.
- chr12:32,985,838–33,923,480, 9 genes, copy number 5: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P.
- chr12:38,078,529–44,389,762, 84 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:18,946,755–22,924,602, 104 genes, copy number 5 (broad region; genes not listed).
- chr13:31,739,526–32,299,125, 6 genes, copy number 5: RXFP2, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1.
- chr15:21,293,653–21,325,241, 3 genes, copy number 5 (within-gene range 1–5): AC068446.1, AC068446.2, RNU6-1235P.
- chr15:83,739,784–83,962,583, 3 genes, copy number 5: TUBAP4, RNU6-1339P, AC027807.2.
- chr15:88,494,440–88,875,353, 10 genes, copy number 5 (within-gene range 4–5): DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN.
- chr15:90,839,641–91,036,611, 20 genes, copy number 5: AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1, PRC1, AC068831.6, PRC1-AS1, Y_RNA, VPS33B, VPS33B-DT, AC068831.5, AC068831.1, AC068831.4, AC068831.2.
- chr15:91,408,708–91,649,114, 3 genes, copy number 5: CRAT37, AC107958.3, AC107958.2.
- chr15:92,470,233–92,620,015, 6 genes, copy number 5 (within-gene range 4–5): AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5.
- chr15:93,230,034–94,168,751, 15 genes, copy number 5: AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40.
- chr15:95,034,108–96,345,651, 23 genes, copy number 5: AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1.
- chr15:100,074,081–100,603,230, 11 genes, copy number 5 (within-gene range 4–5): RNA5SP402, AC022710.1, SPATA41, CERS3-AS1, CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P.
- chr15:101,580,893–101,850,324, 13 genes, copy number 5: AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P.
- chr16:2,047,967–2,135,898, 6 genes, copy number 5 (within-gene range 4–5): TSC2, PKD1, MIR1225, AC009065.2, AC009065.5, MIR6511B1.
- chr16:4,658,851–4,752,565, 6 genes, copy number 5 (within-gene range 4–5): Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71.
- chr16:7,878,799–8,376,276, 5 genes, copy number 5: AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1.
- chr16:9,541,970–9,676,843, 4 genes, copy number 5: AC007221.1, RNA5SP403, RNA5SP404, AC007218.1.
- chr16:10,840,384–10,943,021, 3 genes, copy number 5 (within-gene range 4–5): AC133065.2, AC133065.1, CIITA.
- chr16:11,196,177–11,381,662, 14 genes, copy number 5 (within-gene range 4–5): AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2.
- chr16:19,285,731–19,401,693, 4 genes, copy number 5: CLEC19A, AC130456.1, AC130456.2, AC130456.7.
- chr16:20,409,534–20,487,669, 3 genes, copy number 5: ACSM5, AC137056.1, ACSM2A.
- chr21:10,328,411–13,120,807, 16 genes, copy number 5–8: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
